Somatic mutation profile of tumor specimen TCGA-DB-A64X-01A (aliquot TCGA-DB-A64X-01A-11D-A29Q-08) from TCGA case TCGA-DB-A64X, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 56.5 years (20,625 days).
Specimen TCGA-DB-A64X-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bb5e53d0-cbf9-4af1-b108-c1c5e076eb51.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DB-A64X-10A (Blood Derived Normal), aliquot TCGA-DB-A64X-10A-01D-A29Q-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ce18e0f2-18a6-41e3-a22a-a618bd170036

The open-access MAF lists 79 somatic variants for this specimen: 53 protein-altering or splice-affecting, 24 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 48, Silent 24, Nonsense Mutation 2, Frame Shift Del 2, Intron 1, Splice Region 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 13/34 reads (38%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 12/30 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2
- TP53 | c.658T>C p.Y220H | Missense Mutation (SNP) | VAF 16/45 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs530941076, COSV52691656, COSV52700454, COSV52760651, COSV53630086; ClinVar: likely pathogenic / uncertain significance; called by muse, varscan2
- AHCYL1 | c.179G>A p.R60Q | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.033); catalogued as rs1259490926, COSV63208413; called by muse, mutect2, varscan2
- ALDH3B2 | c.1043T>C p.L348P | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62427827; called by muse, mutect2, varscan2
- ARMCX2 | c.1736A>T p.D579V | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); catalogued as COSV57529581; called by muse, mutect2, varscan2
- BTNL2 | c.1114C>T p.Q372* | Nonsense Mutation (SNP) | VAF 26/187 reads (14%) | catalogued as COSV66630456; called by muse, mutect2, varscan2
- CARMIL3 | c.2592G>C p.R864S | Missense Mutation (SNP) | VAF 37/74 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs781292747, COSV57725556; called by muse, mutect2, varscan2
- CDH6 | c.572A>T p.Y191F | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV54066747; called by muse, mutect2, varscan2
- CDKAL1 | c.692C>T p.A231V | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.085); catalogued as COSV51181312; called by muse, mutect2
- COL4A1 | c.4832C>T p.A1611V | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.067); catalogued as rs775233741, COSV65423218, COSV65434312; called by muse, mutect2
- CSMD3 | c.5971G>T p.D1991Y (on ENST00000297405 / NM_001363185.1; = p.D1887Y on NM_052900.3) | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52098344, COSV52135997; called by muse, mutect2, varscan2
- CXCL5 | c.324C>T p.D108= | Splice Region (SNP) | VAF 39/87 reads (45%) | catalogued as rs573521158, COSV56018381; called by muse, mutect2, varscan2
- CYP4A22 | c.411G>C p.Q137H | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as rs752724599, COSV53739324, COSV53742438; called by muse, mutect2, varscan2
- DGKA | c.125A>G p.Y42C | Missense Mutation (SNP) | VAF 5/100 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.039); catalogued as COSV59385154; called by muse, mutect2
- EML2 | c.1042G>A p.G348R | Missense Mutation (SNP) | VAF 37/103 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); catalogued as rs746967055, COSV55598391; called by muse, mutect2, varscan2
- EPHA8 | c.910G>A p.A304T | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.041); catalogued as rs746880859, COSV51265223; called by muse, mutect2, varscan2
- FANCM | c.3475T>G p.L1159V | Missense Mutation (SNP) | VAF 10/125 reads (8%) | SIFT tolerated (0.47); PolyPhen benign (0.048); catalogued as COSV57498817; called by muse, mutect2
- FAT1 | c.1172C>T p.A391V | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.345); catalogued as COSV71673110; called by muse, mutect2, varscan2
- HERC2 | c.3332C>T p.A1111V | Missense Mutation (SNP) | VAF 38/87 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); catalogued as COSV55314783; called by muse, mutect2, varscan2
- KDM4A | c.890T>C p.I297T | Missense Mutation (SNP) | VAF 6/91 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64959126; called by muse, mutect2
- KRT28 | c.592C>T p.R198* | Nonsense Mutation (SNP) | VAF 9/86 reads (10%) | catalogued as rs200021509, COSV60684513; called by muse, mutect2, varscan2
- KRTAP10-12 | c.496T>C p.C166R | Missense Mutation (SNP) | VAF 163/396 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59956344; called by muse, mutect2, varscan2
- KRTAP10-3 | c.487C>T p.R163C | Missense Mutation (SNP) | VAF 22/224 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs373472330; called by muse, mutect2, varscan2
- LGSN | c.283C>A p.L95I | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.801); catalogued as COSV65726232, COSV65726584; called by muse, mutect2, varscan2
- LMNTD2 | c.793G>A p.V265M | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as COSV54239420; called by muse, mutect2, varscan2
- MAPK1 | c.788A>G p.Y263C | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.495); catalogued as COSV53185588; called by muse, mutect2, varscan2
- MCTP2 | c.2375C>T p.T792M | Missense Mutation (SNP) | VAF 43/91 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs570221748, COSV63292520, COSV63298220; called by muse, mutect2, varscan2
- MED26 | c.89C>T p.A30V | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.696); catalogued as rs752459319, COSV54658810; called by muse, mutect2, varscan2
- MIA3 | c.1018A>G p.K340E | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.45); catalogued as COSV60511402; called by muse, mutect2, varscan2
- MMRN1 | c.76T>C p.S26P | Missense Mutation (SNP) | VAF 29/131 reads (22%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as COSV53335383; called by muse, mutect2, varscan2
- MUC5B | c.13036G>A p.A4346T | Missense Mutation (SNP) | VAF 24/190 reads (13%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0.137); catalogued as COSV71590928; called by muse, mutect2, varscan2
- NFX1 | c.1433A>G p.E478G | Missense Mutation (SNP) | VAF 35/126 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0.029); catalogued as COSV59309162; called by muse, mutect2, varscan2
- PMS2 | c.106A>C p.S36R | Missense Mutation (SNP) | VAF 69/295 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as rs587781918, COSV56150278; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PRDM2 | c.2971C>G p.P991A | Missense Mutation (SNP) | VAF 9/138 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as rs1199492884, COSV52444459; called by muse, mutect2
- PUS7 | c.1877A>T p.D626V | Missense Mutation (SNP) | VAF 46/99 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.505); catalogued as COSV62676281; called by muse, mutect2, varscan2
- RAB3GAP2 | c.1282G>A p.A428T | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs773249438, COSV52964786; called by muse, mutect2
- RASGRF2 | c.1385G>A p.R462H | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs1329580753, COSV54126312; called by muse, mutect2, varscan2
- RGMB | c.1247C>G p.P416R (on ENST00000513185 / NM_001366508.1; = p.P457R on NM_001012761.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as rs988899253, COSV57564946; called by muse, mutect2, varscan2
- SEPTIN11 | c.794A>G p.E265G | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV53581276; called by muse, mutect2, varscan2
- SLC2A14 | c.344G>A p.R115H | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.536); catalogued as rs374655537, COSV100533574, COSV61585766; called by muse, mutect2, varscan2
- STAB1 | c.5711G>T p.S1904I | Missense Mutation (SNP) | VAF 22/449 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.031); catalogued as COSV58733889; called by muse, mutect2
- STIMATE | c.589G>A p.V197I | Missense Mutation (SNP) | VAF 11/143 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61890671; called by muse, mutect2
- SYTL1 | c.299A>T p.D100V | Missense Mutation (SNP) | VAF 6/83 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV58870957; called by muse, mutect2
- TBC1D25 | c.895C>T p.H299Y | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as COSV65123422; called by muse, mutect2, varscan2
- THSD7A | c.2956A>G p.K986E | Missense Mutation (SNP) | VAF 21/142 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.269); catalogued as COSV70262433; called by muse, mutect2, varscan2
- TMEM132A | c.943C>T p.R315C | Missense Mutation (SNP) | VAF 78/175 reads (45%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.809); catalogued as rs571711270, COSV50003084; called by muse, mutect2, varscan2
- TMPRSS11F | c.878A>G p.D293G | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs145412545; called by muse, mutect2, varscan2
- TRPA1 | c.1372C>T p.R458C | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374228201; called by muse, mutect2, varscan2
- TRPV5 | c.1630C>T p.P544S | Missense Mutation (SNP) | VAF 54/113 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54684152; called by muse, mutect2, varscan2
- TTN | c.100556T>C p.V33519A (on ENST00000591111; = p.V26095A on NM_003319.4) | Missense Mutation (SNP) | VAF 91/232 reads (39%) | PolyPhen benign (0.343); catalogued as COSV59957271; called by muse, mutect2, varscan2
- POLR3A | c.224del p.N75Tfs*6 | Frame Shift Del (DEL) | VAF 23/115 reads (20%) | called by mutect2, pindel, varscan2
- TAOK1 | c.12_15del p.N5Efs*5 | Frame Shift Del (DEL) | VAF 15/41 reads (37%) | called by mutect2, pindel, varscan2
- ARMCX5 | c.402T>A p.I134= | Silent (SNP) | VAF 20/266 reads (8%) | catalogued as COSV55766168; called by muse, mutect2
- CCDC116 | c.150C>T p.S50= | Silent (SNP) | VAF 12/178 reads (7%) | catalogued as COSV53037351; called by muse, mutect2
- FAM47C | c.1341G>T p.V447= | Silent (SNP) | VAF 59/137 reads (43%) | catalogued as COSV63725203; called by muse, mutect2, varscan2
- FANCD2 | c.3195G>A p.L1065= | Silent (SNP) | VAF 7/170 reads (4%) | catalogued as COSV55035291; called by muse, mutect2
- FRMPD3 | c.1359C>T p.G453= | Silent (SNP) | VAF 26/103 reads (25%) | catalogued as rs1207294499, COSV52187119; called by muse, mutect2, varscan2
- GMIP | c.1725A>C p.I575= | Silent (SNP) | VAF 60/141 reads (43%) | catalogued as COSV52555144; called by muse, mutect2, varscan2
- HRC | c.1524C>T p.G508= | Silent (SNP) | VAF 12/49 reads (24%) | catalogued as rs1476871647, COSV53255726; called by muse, mutect2, varscan2
- HSPG2 | c.11181C>T p.G3727= | Silent (SNP) | VAF 49/89 reads (55%) | catalogued as COSV65932929; called by muse, mutect2, varscan2
- ITPR3 | c.615C>T p.A205= | Silent (SNP) | VAF 57/124 reads (46%) | catalogued as rs755640976, COSV65407262; called by muse, mutect2, varscan2
- KLHL28 | c.975A>G p.G325= | Silent (SNP) | VAF 4/60 reads (7%) | catalogued as COSV61887707; called by muse, mutect2
- KRT31 | c.72C>G p.P24= | Silent (SNP) | VAF 33/83 reads (40%) | catalogued as rs761953088, COSV52434128; called by muse, mutect2, varscan2
- L1CAM | c.3015C>A p.I1005= | Silent (SNP) | VAF 63/236 reads (27%) | catalogued as COSV62827414; called by muse, mutect2, varscan2
- LTV1 | c.369A>C p.G123= | Silent (SNP) | VAF 4/76 reads (5%) | catalogued as COSV62536284; called by muse, mutect2
- MMRN1 | c.837A>G p.K279= | Silent (SNP) | VAF 15/25 reads (60%) | catalogued as COSV53335393; called by muse, mutect2, varscan2
- NEGR1 | c.657T>C p.V219= | Silent (SNP) | VAF 18/33 reads (55%) | catalogued as COSV60837329; called by muse, mutect2, varscan2
- PCSK6 | c.522C>T p.G174= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as rs780908321, COSV59339490; called by muse, mutect2, varscan2
- PMEL | c.1881A>G p.V627= | Silent (SNP) | VAF 29/89 reads (33%) | catalogued as rs1461310761, COSV59385163; called by muse, mutect2, varscan2
- RELA | c.276A>G p.G92= | Silent (SNP) | VAF 14/99 reads (14%) | catalogued as COSV58014224; called by muse, mutect2, varscan2
- RFX6 | c.1572T>C p.I524= | Silent (SNP) | VAF 6/81 reads (7%) | catalogued as COSV60584116; called by muse, mutect2
- RLIM | c.801C>T p.H267= | Silent (SNP) | VAF 8/121 reads (7%) | catalogued as COSV60325816; called by muse, mutect2
- RYK | c.1638C>T p.Y546= (on ENST00000620660 / NM_001005861.2; = p.Y543= on NM_002958.4) | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as rs373422007; called by muse, mutect2, varscan2
- SIGLEC1 | c.4674C>T p.S1558= | Silent (SNP) | VAF 5/10 reads (50%) | catalogued as rs1416867668, COSV52460730; called by muse, mutect2, varscan2
- TEX15 | c.7803A>C p.I2601= (on ENST00000256246; = p.I2984= on NM_001350162.2) | Silent (SNP) | VAF 27/64 reads (42%) | catalogued as COSV56343811; called by muse, mutect2, varscan2
- TRIML1 | c.765G>A p.E255= | Silent (SNP) | VAF 5/35 reads (14%) | catalogued as rs1291387868, COSV60193779; called by muse, mutect2, varscan2
- TTN | c.10360+5101G>A | Intron (SNP) | VAF 3/33 reads (9%) | catalogued as COSV100614992; called by muse, mutect2
- WASF4P | n.1493A>T | RNA (SNP) | VAF 14/57 reads (25%) | called by muse, mutect2, varscan2
